Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A902, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A902-01A (Primary Tumor).

Patient Name: [REDACTED]
DOB: [REDACTED]

MRN: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

* Consult Report *

ICD-O-3
Carcinoma, squamous
cell NOS 867613

Site: Cervix NOS 253.9

9/21/14

FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Service: [REDACTED]

Location: [REDACTED]

Accession #: [REDACTED]

Taken: [REDACTED]

Gender: F

DOB: [REDACTED]

Age: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Received: [REDACTED]

Accessioned: [REDACTED]

Reported: [REDACTED]

Physician(s): [REDACTED] M.D.

DIAGNOSIS

UTERUS, CERVIX, BIOPSY

- INVASIVE POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA ARISING IN SEVERE
SQUAMOUS DYSPLASIA (CIN3) INVADING THE ENTIRE TISSUE THICKNESS (5 MM) (SEE COMMENT)

By this signature, I attest that the above diagnosis is based upon my personal
examination of the slide(s) and/or other material indicated in the diagnosis.

[REDACTED] MD

***Report Electronically Reviewed and Signed Out By

[REDACTED] MD***

Microscopic Description and Comment:

The tumor involves all the tissue material on the slide, and has a thickness of at least 5 mm. It is a solid poorly
differentiated squamous cell carcinoma arising in severe squamous dysplasia (CIN 3). While there is cytoplasmic
clearing in many areas of the tumor, the cytologic atypia is not as severe as that seen in clear cell carcinoma. In
addition, a single pattern is seen, solid, while clear cell carcinomas usually are composed of multiple patterns,
glandular and papillary in addition to the solid pattern. Further support of the squamous origin of this tumor is that it is
arising in squamous dysplasia.

History:

(Not Provided)

Materials Received:

Received one slide labeled [REDACTED] and sublabelled 2. The material is accompanied by a corresponding

Source: NCI Genomic Data Commons file bfff577f-a3ec-4704-b315-f2531876119d (TCGA-C5-A902.72D0C467-BF42-45A3-B472-00652B7B1705.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).